Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5VV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5VV-06A (Metastatic).

Gross Description: 1) There is a skin flap with a post-operative scar up to 7 cm in size. In the subcutaneous tissue there is a node with necrosis up to 2.5 cm in size.

2) There is a fatty tissue fragment with a metastatic gray-black node up to 2 cm in its size.

Microscopic Description: Malignant melanoma of the skin, recurrent, with superficial ulceration and large foci of necrosis. Tumor thickness is more than 4 mm. One examined lymph node demonstrated metastases of the malignant melanoma.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: Other, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Original records read pN1b. For the TCGA project tumor sample was taken from the lymph node tissue.

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Lymph node, inguinal

Tumor size: 0 x 0 x 2.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Metastatic neoplasm, malignant melanoma

Histologic grade: Not specified

Lymph nodes: 1/1 positive for metastasis (Inguinal lymph node 1/1)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

*ICD-O-3
Melanoma, malignant 8720/3
Site Lymph Node, inguinal 177.4
JW 3/18/13*

Source: NCI Genomic Data Commons file 4a20c66c-b6fe-4ced-a93b-d8be6460be3d (TCGA-EB-A5VV.19D99676-CF74-4E8F-B6EF-CCF5A7578D77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).